Somatic mutation profile of tumor specimen TCGA-UY-A78L-01A (aliquot TCGA-UY-A78L-01A-12D-A339-08) from TCGA case TCGA-UY-A78L, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 62.2 years (22,717 days).
Specimen TCGA-UY-A78L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4d3c930-8bee-44a0-9c4f-d7d6fd256422.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UY-A78L-10A (Blood Derived Normal), aliquot TCGA-UY-A78L-10A-01D-A339-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39b0e9ab-c8f9-484e-9060-7843fe1a9dc7

The open-access MAF lists 231 somatic variants for this specimen: 159 protein-altering or splice-affecting, 65 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 138, Silent 65, Nonsense Mutation 13, Frame Shift Del 4, Splice Site 3, Intron 3, 3'UTR 2, 5'Flank 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.335T>C p.L112P | Missense Mutation (SNP) | VAF 56/100 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121909230, CM981669, COSV64294101, COSV64304040; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.2520+3_2520+6del p.X840_splice | Splice Site (DEL) | VAF 33/77 reads (43%) | catalogued as rs1131690858; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 32/50 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AANAT | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as COSV51684138; called by muse, mutect2, varscan2
- ADAMTS20 | c.3575G>C p.C1192S | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67129692; called by muse, mutect2, varscan2
- ADD2 | c.1696G>C p.E566Q | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.325); catalogued as COSV52458470; called by muse, mutect2, varscan2
- AKAP13 | c.5210C>T p.S1737F (on ENST00000394518 / NM_007200.5; = p.S1741F on NM_006738.6) | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63453082; called by muse, mutect2, varscan2
- ANKRD34A | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60160662, COSV60160673; called by muse, mutect2, varscan2
- ANKS4B | c.937G>T p.E313* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100289722; called by muse, mutect2, varscan2
- APC2 | c.2855C>T p.S952L | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as rs913282943, COSV52017315; called by muse, mutect2, varscan2
- APOB | c.3523G>C p.E1175Q | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as COSV51950991; called by muse, mutect2
- APOBEC3B | c.326C>G p.S109C | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV59840642; called by muse, mutect2, varscan2
- ARHGEF6 | c.1255C>G p.Q419E | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.741); catalogued as COSV51689238; called by muse, mutect2, varscan2
- ARVCF | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.586); catalogued as COSV54266020; called by muse, mutect2, varscan2
- ASNSD1 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs974787806, COSV53623390; called by muse, mutect2, varscan2
- ATP11C | c.1929G>A p.M643I | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV59561895; called by muse, mutect2, varscan2
- ATP1B4 | c.628G>T p.D210Y (on ENST00000218008 / NM_001142447.3; = p.D206Y on NM_012069.5) | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54311971; called by muse, mutect2
- ATP23 | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); catalogued as COSV100274422; called by muse, mutect2, varscan2
- ATP5F1C | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.213); catalogued as rs550053511, COSV59621371; called by muse, mutect2, varscan2
- ATRX | c.6798G>C p.L2266F | Missense Mutation (SNP) | VAF 89/131 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64874395; called by muse, mutect2, varscan2
- BGLAP | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.619); catalogued as rs1161350114, COSV52744778, COSV99430762; called by muse, mutect2, varscan2
- BIRC7 | c.745G>A p.E249K (on ENST00000217169 / NM_139317.3; = p.E231K on NM_022161.4) | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV53900817; called by muse, mutect2, varscan2
- CATSPERD | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV58464946; called by muse, mutect2, varscan2
- CCDC17 | c.1612G>C p.E538Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100601680; called by muse, mutect2
- CD109 | c.649C>G p.Q217E | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV54647934, COSV54655580; called by muse, mutect2, varscan2
- CDC25B | c.784G>C p.E262Q (on ENST00000245960 / NM_021873.3; = p.E248Q on NM_004358.4) | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV55655568; called by muse, varscan2
- CDC25B | c.1138G>C p.E380Q (on ENST00000245960 / NM_021873.3; = p.E366Q on NM_004358.4) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.08); catalogued as COSV55655601, COSV55656956; called by muse, mutect2, varscan2
- CELF1 | c.764-2A>G p.X255_splice (on ENST00000358597 / NM_001376422.1; = p.X251_splice on NM_006560.4 and 10 other RefSeq transcripts) | Splice Site (SNP) | VAF 13/59 reads (22%) | catalogued as COSV60111057; called by muse, mutect2, varscan2
- CEP85 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs373834084; called by muse, mutect2, varscan2
- CHD7 | c.181C>G p.Q61E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.053); catalogued as COSV71108845; called by muse, mutect2, varscan2
- CLK1 | c.678G>C p.Q226H | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as COSV58433021; called by muse, mutect2, varscan2
- CLK1 | c.593G>C p.R198T | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as COSV58433041; called by muse, mutect2, varscan2
- CLSTN2 | c.1132C>G p.Q378E | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.609); catalogued as COSV71719861; called by muse, mutect2, varscan2
- COL4A1 | c.4091C>G p.P1364R | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as COSV101011001; called by muse, mutect2, varscan2
- COL9A1 | c.2543G>T p.R848I | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV57881819; called by muse, mutect2, varscan2
- CRISP3 | c.440G>T p.W147L (on ENST00000371159 / NM_001368123.1; = p.W129L on NM_006061.4) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53819868; called by muse, mutect2, varscan2
- CSN3 | c.175G>C p.G59R | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV59243868; called by muse, mutect2, varscan2
- CSTF1 | c.710A>T p.Q237L | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.289); catalogued as COSV53858462; called by muse, mutect2, varscan2
- CUL9 | c.2530G>C p.E844Q | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.419); catalogued as COSV52727320; called by muse, mutect2, varscan2
- DCAF1 | c.4433C>T p.A1478V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.024); catalogued as COSV60041940; called by muse, mutect2, varscan2
- DCTN1 | c.1840C>T p.R614C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62620171; called by muse, mutect2, varscan2
- DDX4 | c.425C>G p.S142* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100737373; called by muse, mutect2, varscan2
- DEAF1 | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as rs368628431; called by muse, mutect2, varscan2
- DENND4B | c.4408G>A p.E1470K | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.495); catalogued as COSV63408241; called by muse, mutect2, varscan2
- DMD | c.2656C>G p.Q886E | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs754893725, COSV63745770; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMXL1 | c.6497C>G p.S2166* | Nonsense Mutation (SNP) | VAF 21/101 reads (21%) | catalogued as COSV100223478; called by muse, mutect2, varscan2
- DNAH3 | c.3874A>G p.I1292V | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV54514442; called by muse, mutect2, varscan2
- DOP1A | c.5609G>A p.R1870K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.965); catalogued as COSV52708727; called by muse, mutect2, varscan2
- DTL | c.1032G>A p.W344* | Nonsense Mutation (SNP) | VAF 21/85 reads (25%) | catalogued as rs763877768, COSV100877160; called by muse, mutect2, varscan2
- ELN | c.2138C>T p.A713V (on ENST00000320399 / NM_001278939.1; = p.A680V on NM_000501.4) | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.271); catalogued as COSV52709130; called by muse, mutect2, varscan2
- EVC2 | c.668C>G p.S223W | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV60391041; called by muse, mutect2, varscan2
- FABP9 | c.221C>T p.T74I | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV66911502; called by muse, mutect2, varscan2
- FAT4 | c.4709G>T p.G1570V | Missense Mutation (SNP) | VAF 73/119 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67883879; called by muse, mutect2, varscan2
- FBLN7 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55615876; called by muse, mutect2, varscan2
- FLG | c.8909C>A p.A2970E | Missense Mutation (SNP) | VAF 75/557 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV100910915; called by muse, mutect2, varscan2
- FMN2 | c.3985G>C p.E1329Q | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV60425807; called by muse, mutect2, varscan2
- FREM2 | c.8668G>A p.E2890K | Missense Mutation (SNP) | VAF 53/330 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV54831147; called by muse, mutect2, varscan2
- GABRG1 | c.1331G>T p.R444I | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1278404481, COSV54952155; called by muse, mutect2, varscan2
- GALE | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs528467258, CM054731, COSV52525176; called by muse, mutect2, varscan2
- GCC2 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 50/80 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV59175412; called by muse, mutect2, varscan2
- GPANK1 | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs776206467, COSV63263709; called by muse, mutect2, varscan2
- GPR141 | c.419G>T p.W140L | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57731879; called by muse, mutect2, varscan2
- GTF2H3 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV99967520; called by muse, mutect2
- HERC5 | c.2354A>G p.N785S | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV52038758; called by muse, mutect2
- HOXD4 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0.03); catalogued as COSV100106725; called by muse, mutect2
- IVNS1ABP | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs752321106, COSV62250815; called by muse, mutect2, varscan2
- KCNH5 | c.678C>G p.F226L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.574); catalogued as COSV59756732; called by muse, mutect2, varscan2
- KIF20B | c.1463C>G p.S488C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV53305261; called by muse, mutect2, varscan2
- KIF5C | c.611G>A p.R204K | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV68480628, COSV68480921; called by muse, varscan2
- KLHL5 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as COSV54671728; called by muse, mutect2, varscan2
- KLHL9 | c.1828C>G p.L610V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.328); catalogued as COSV62921415; called by muse, mutect2, varscan2
- KLK10 | c.639G>C p.M213I | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59397829; called by muse, mutect2, varscan2
- KRT8 | c.588C>G p.I196M | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); catalogued as COSV53176746; called by muse, mutect2, varscan2
- KSR2 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.02); catalogued as rs768799651, COSV56669801; called by muse, mutect2, varscan2
- LRIG1 | c.1616A>T p.N539I | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV56238798, COSV56247594; called by muse, mutect2, varscan2
- MAB21L2 | c.168G>C p.L56F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV58261389; called by muse, mutect2, varscan2
- MAPK6 | c.1366A>G p.N456D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV99958974; called by muse, varscan2
- MAPK8IP3 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.445); catalogued as COSV51718575; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.32); catalogued as COSV51718592; called by muse, mutect2, varscan2
- MMP25 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs750900917, COSV60679069; called by muse, mutect2, varscan2
- MMP25 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.82); catalogued as COSV60679082; called by muse, mutect2, varscan2
- MS4A1 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV61941958; called by muse, mutect2, varscan2
- MUC16 | c.19750G>C p.E6584Q | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as COSV67457699; called by muse, mutect2, varscan2
- MYH3 | c.4790C>T p.T1597I | Missense Mutation (SNP) | VAF 177/306 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV56863285; called by muse, mutect2, varscan2
- NALCN | c.3611A>T p.Y1204F | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV51927714, COSV51954163; called by muse, mutect2, varscan2
- NDST1 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV55786069; called by muse, mutect2, varscan2
- NDUFV2 | c.725G>C p.G242A | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); catalogued as COSV50821964; called by muse, mutect2, varscan2
- NFXL1 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV61198528; called by muse, mutect2, varscan2
- NNT | c.1540C>G p.H514D | Missense Mutation (SNP) | VAF 36/672 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV52924077, COSV99239211; called by muse, mutect2
- NPY2R | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100279834, COSV61527396; called by muse, mutect2, varscan2
- NR0B2 | c.652C>T p.L218F | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV54259447, COSV99575111; called by muse, mutect2, varscan2
- NRCAM | c.47G>C p.R16T | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV61030439, COSV61035172; called by muse, mutect2, varscan2
- NRXN2 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs1238286270, COSV55446744; called by muse, mutect2, varscan2
- OLFML3 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.109); catalogued as rs561647873, COSV57435042; called by mutect2, varscan2
- OR12D3 | c.752A>G p.Y251C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as rs891676965, COSV65827172; called by muse, mutect2, varscan2
- OR2A25 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV68717058; called by muse, mutect2, varscan2
- OR6B1 | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68769977; called by muse, mutect2, varscan2
- P2RX2 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as rs1385389415, COSV100265657; called by muse, mutect2, varscan2
- PACSIN1 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 37/237 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV55059392; called by muse, mutect2, varscan2
- PCDH11X | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100009284; called by muse, mutect2, varscan2
- PDCD4 | c.1078C>A p.H360N | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54522371; called by muse, mutect2, varscan2
- PDS5A | c.3156G>C p.K1052N | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as COSV57824470; called by muse, mutect2, varscan2
- PELI2 | c.799C>G p.Q267E | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.389); catalogued as COSV50710567; called by muse, mutect2, varscan2
- PIAS3 | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 79/224 reads (35%) | catalogued as COSV100992659; called by muse, mutect2, varscan2
- PIBF1 | c.1863G>C p.Q621H | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV58322011; called by muse, mutect2
- PLXDC2 | c.250C>A p.Q84K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as COSV65914213; called by muse, mutect2, varscan2
- PPL | c.4132G>C p.E1378Q | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52167230; called by muse, mutect2
- PROKR2 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54085881; called by muse, mutect2, varscan2
- PTN | c.290C>A p.A97E | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV61964495, COSV61965937; called by muse, mutect2
- RAD54L | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58439560; called by muse, mutect2, varscan2
- RAI14 | c.1867G>A p.A623T | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV54292359; called by muse, mutect2
- RAPGEF4 | c.3028C>G p.R1010G | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs761012829, COSV51383733; called by muse, mutect2, varscan2
- RASGRP3 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as COSV67821374; called by muse, mutect2, varscan2
- RBM5 | c.184-1G>A p.X62_splice | Splice Site (SNP) | VAF 40/106 reads (38%) | catalogued as COSV61737100; called by muse, mutect2, varscan2
- RGL4 | c.1094G>A p.S365N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.331); catalogued as rs769625983, COSV51943559; called by muse, mutect2, varscan2
- RIPK1 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as COSV52528757; called by muse, mutect2, varscan2
- RNF111 | c.1813C>T p.Q605* | Nonsense Mutation (SNP) | VAF 25/99 reads (25%) | catalogued as rs1055168382, COSV62085730; called by muse, mutect2, varscan2
- RPTOR | c.915G>T p.R305S | Missense Mutation (SNP) | VAF 24/472 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60806368; called by muse, mutect2
- SALL2 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV100444201; called by muse, mutect2, varscan2
- SBNO1 | c.3040G>C p.E1014Q (on ENST00000420886; = p.E1013Q on NM_018183.5) | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57340491; called by muse, mutect2, varscan2
- SHANK2 | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV53593089; called by muse, mutect2, varscan2
- SKIL | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52059206; called by muse, mutect2, varscan2
- SLC24A1 | c.3252C>G p.I1084M | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as COSV56051092; called by muse, mutect2, varscan2
- SLC25A30 | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60433571; called by muse, mutect2, varscan2
- SLC5A1 | c.1610C>G p.S537C | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as COSV56684497; called by muse, mutect2, varscan2
- SLC66A3 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.957); catalogued as COSV54466754; called by muse, mutect2, varscan2
- SLTM | c.998A>G p.K333R | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs1273358633, COSV51053776; called by muse, mutect2, varscan2
- SP100 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.168); catalogued as COSV99892554; called by muse, mutect2
- SPATC1 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV66298541; called by muse, mutect2, varscan2
- SRCAP | c.7443C>G p.I2481M | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.147); catalogued as COSV52670327; called by muse, mutect2, varscan2
- SUPT6H | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as COSV58926458; called by muse, mutect2, varscan2
- SYT2 | c.143A>G p.K48R | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV66141705; called by muse, mutect2, varscan2
- TCHH | c.4237G>A p.D1413N | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.083); catalogued as COSV64273976; called by muse, mutect2, varscan2
- TEAD1 | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV57563158; called by muse, mutect2, varscan2
- TMEM62 | c.770A>G p.H257R | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53040641; called by muse, mutect2, varscan2
- TNFAIP3 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.773); catalogued as rs918962406, COSV52798062; called by muse, mutect2, varscan2
- TRDN | c.182C>G p.S61* | Nonsense Mutation (SNP) | VAF 22/75 reads (29%) | catalogued as COSV100521104; called by muse, mutect2, varscan2
- TRIM39-RPP21 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV64955166; called by muse, mutect2, varscan2
- TTN | c.20654C>T p.S6885F (on ENST00000591111; = p.S5958F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | PolyPhen benign (0.178); catalogued as COSV59978227; called by muse, mutect2, varscan2
- TTN | c.6907G>T p.D2303Y (on ENST00000591111; = p.D2257Y on NM_003319.4) | Missense Mutation (SNP) | VAF 21/108 reads (19%) | PolyPhen possibly damaging (0.518); catalogued as COSV59978249, COSV60274688; called by muse, mutect2, varscan2
- TUBB6 | c.1078G>A p.G360S | Missense Mutation (SNP) | VAF 41/288 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV52313849; called by muse, mutect2, varscan2
- USP29 | c.2215G>C p.E739Q | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.448); catalogued as COSV54141542, COSV54141783; called by muse, mutect2, varscan2
- VCX3A | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV101129809; called by muse, mutect2, varscan2
- VPS13D | c.7562G>T p.R2521L | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.838); catalogued as COSV50631052; called by muse, mutect2, varscan2
- XPO6 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58963785; called by muse, mutect2, varscan2
- ZFHX4 | c.10456C>T p.H3486Y | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1348541400, COSV50664812; called by muse, mutect2, varscan2
- ZNF37A | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 20/90 reads (22%) | catalogued as COSV100697296; called by muse, mutect2, varscan2
- ZNF564 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV59434766; called by muse, mutect2, varscan2
- ZNF70 | c.313C>G p.Q105E | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV59532596; called by muse, varscan2
- ZNF70 | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 48/140 reads (34%) | catalogued as COSV59532029; called by muse, varscan2
- ZNF827 | c.3142G>C p.E1048Q | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV65226133; called by muse, mutect2, varscan2
- CACNG7 | c.306del p.F103Sfs*59 | Frame Shift Del (DEL) | VAF 23/74 reads (31%) | called by mutect2, pindel, varscan2
- CCDC136 | c.2832del p.R945Gfs*4 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- CDKN1A | c.253_260del p.G85* | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- HSPA8 | c.1896dup p.S633Lfs*11 | Frame Shift Ins (INS) | VAF 35/103 reads (34%) | called by mutect2, pindel, varscan2
- KDM6A | c.3070G>A p.E1024K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2
- NCOR1 | c.2850del p.I950Mfs*5 | Frame Shift Del (DEL) | VAF 46/92 reads (50%) | called by mutect2, pindel, varscan2
- PABPC4 | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.101); called by muse, mutect2
- PRAMEF15 | c.910A>T p.T304S | Missense Mutation (SNP) | VAF 54/282 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- ABCC12 | c.1245C>G p.L415= | Silent (SNP) | VAF 44/94 reads (47%) | catalogued as rs1479500261, COSV60912984; called by muse, mutect2, varscan2
- AGTR1 | c.690G>A p.K230= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs201574669, COSV62557728; called by muse, mutect2, varscan2
- ANAPC1 | c.1572A>C p.T524= | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as COSV61974330, COSV61975254; called by muse, mutect2, varscan2
- B3GALT4 | c.1136G>A p.*379= | Silent (SNP) | VAF 24/133 reads (18%) | catalogued as COSV101005579; called by muse, mutect2, varscan2
- BOC | c.1137C>G p.L379= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99848296; called by muse, mutect2
- BTN3A3 | c.762G>C p.G254= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as COSV55071452; called by muse, mutect2, varscan2
- CD1D | c.375G>A p.G125= | Silent (SNP) | VAF 20/306 reads (7%) | catalogued as COSV63808757; called by muse, mutect2
- CNTRL | c.3108C>T p.L1036= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as COSV53045566; called by muse, mutect2, varscan2
- COL6A1 | c.1797C>T p.I599= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV62612561; called by muse, mutect2, varscan2
- CR2 | c.579G>A p.K193= | Silent (SNP) | VAF 19/135 reads (14%) | catalogued as COSV100889721, COSV65507002; called by muse, mutect2, varscan2
- CRYBG1 | c.3942C>T p.F1314= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as COSV64811604; called by muse, mutect2, varscan2
- CSPP1 | c.1830G>C p.L610= (on ENST00000676605; = p.L569= on NM_024790.6) | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV51582628; called by muse, mutect2, varscan2
- CUBN | c.1137C>G p.L379= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV64710207, COSV64712724; called by muse, mutect2
- CUL7 | c.2214G>A p.V738= | Silent (SNP) | VAF 63/160 reads (39%) | catalogued as rs549059005, COSV54815081; called by muse, mutect2, varscan2
- DLD | c.195C>T p.F65= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV52737489; called by muse, mutect2, varscan2
- DNAH5 | c.4686C>T p.F1562= | Silent (SNP) | VAF 18/320 reads (6%) | catalogued as rs751766956, COSV54216630; ClinVar: likely benign; called by muse, mutect2
- DRD2 | c.981G>A p.K327= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV100669279, COSV60756609; called by muse, mutect2, varscan2
- DYNC2H1 | c.6469C>T p.L2157= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV62106804; called by muse, mutect2
- EDNRA | c.1182G>A p.L394= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV60096510; called by muse, mutect2, varscan2
- FANCG | c.541C>T p.L181= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV62720098; called by muse, mutect2, varscan2
- FNTB | c.1308C>T p.T436= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs556849979, COSV55760825; called by muse, mutect2, varscan2
- GJB4 | c.360G>C p.L120= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV58355887; called by muse, mutect2, varscan2
- GRM8 | c.675G>A p.G225= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV58804859; called by muse, mutect2, varscan2
- HELLS | c.1926C>T p.F642= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as COSV53295823; called by muse, mutect2, varscan2
- IRX2 | c.660C>T p.I220= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs756601056, COSV100121621; called by muse, mutect2, varscan2
- KCNA10 | c.303C>G p.L101= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV63904496; called by muse, mutect2, varscan2
- KCNQ5 | c.2707C>T p.L903= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV59655760; called by muse, mutect2, varscan2
- KIRREL3 | c.720G>A p.T240= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs754939539, COSV73105296; called by muse, mutect2, varscan2
- LPCAT1 | c.1539C>T p.F513= | Silent (SNP) | VAF 8/188 reads (4%) | catalogued as COSV52036784; called by muse, mutect2
- LRRIQ4 | c.591G>A p.E197= | Silent (SNP) | VAF 18/138 reads (13%) | catalogued as COSV61618950; called by muse, mutect2, varscan2
- LRRTM3 | c.1485G>A p.L495= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV63663791; called by muse, mutect2, varscan2
- LTB4R | c.459C>G p.L153= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as rs375670032, COSV51865274; called by muse, mutect2, varscan2
- LURAP1L | c.27C>T p.L9= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV59984204; called by muse, mutect2, varscan2
- MCCC1 | c.717C>T p.F239= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV55607822, COSV99659497; called by muse, mutect2, varscan2
- MRPL38 | c.579G>A p.V193= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV99485344; called by muse, mutect2
- MYH7B | c.4725G>A p.E1575= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99327957; called by muse, mutect2
- NARF | c.240G>A p.L80= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV59111344; called by muse, varscan2
- NDST1 | c.1447C>A p.R483= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as COSV55784704, COSV55786084; called by muse, mutect2, varscan2
- NOBOX | c.204C>G p.L68= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV56194901, COSV99779257; called by muse, mutect2, varscan2
- OR5H14 | c.375C>T p.A125= | Silent (SNP) | VAF 26/211 reads (12%) | catalogued as COSV71193505; called by muse, mutect2, varscan2
- PCDHGA10 | c.1599G>A p.Q533= | Silent (SNP) | VAF 76/233 reads (33%) | catalogued as COSV53926116, COSV53993548; called by muse, mutect2, varscan2
- PCF11 | c.1347C>A p.I449= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV53529592; called by muse, mutect2, varscan2
- PDXDC1 | c.2232C>T p.L744= | Silent (SNP) | VAF 61/159 reads (38%) | catalogued as rs748794793, COSV55074025; called by muse, mutect2, varscan2
- PPM1E | c.1716C>T p.L572= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV57572582; called by muse, mutect2, varscan2
- PSMC6 | c.318G>A p.L106= (on ENST00000612399; = p.L92= on NM_002806.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV71628675; called by muse, mutect2, varscan2
- PTBP1 | c.1329C>T p.S443= (on ENST00000349038 / NM_031991.4; = p.S469= on NM_002819.5) | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV62459371; called by muse, mutect2, varscan2
- RFC4 | c.1047C>T p.I349= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs754962980, COSV56216462; called by mutect2, varscan2
- RGS6 | c.1296G>A p.L432= | Silent (SNP) | VAF 59/130 reads (45%) | catalogued as COSV59571324; called by muse, mutect2, varscan2
- RNF213 | c.10125C>T p.L3375= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV60394553; called by mutect2, varscan2
- SEMA6C | c.855C>T p.L285= | Silent (SNP) | VAF 35/282 reads (12%) | catalogued as COSV59001771; called by muse, mutect2, varscan2
- SF1 | c.273G>T p.G91= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV57112701; called by muse, mutect2, varscan2
- SLC13A3 | c.868C>T p.L290= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as rs890958568, COSV99286316; called by muse, mutect2
- SLC5A2 | c.807C>G p.P269= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100393358, COSV57890968, COSV57891426; called by muse, mutect2, varscan2
- SOX9 | c.834G>A p.L278= | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as COSV55423356, COSV55424109, COSV55428800; called by muse, mutect2, varscan2
- SRSF2 | c.618G>A p.S206= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as COSV57969978, COSV57971197; called by muse, mutect2
- SYMPK | c.1938C>T p.L646= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as rs1437191593, COSV55610769; called by muse, mutect2, varscan2
- TASOR2 | c.4441C>T p.L1481= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV60166803, COSV60167343; called by muse, mutect2, varscan2
- TLR9 | c.633C>T p.L211= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV59726133; called by muse, mutect2, varscan2
- TMC4 | c.15G>C p.P5= | Silent (SNP) | VAF 25/147 reads (17%) | catalogued as COSV55475117; called by muse, mutect2, varscan2
- TMEM97 | c.456C>T p.L152= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs1555575531, COSV56878550; called by muse, mutect2, varscan2
- TNFRSF19 | c.441G>A p.P147= | Silent (SNP) | VAF 29/40 reads (73%) | catalogued as rs143483716; called by muse, mutect2, varscan2
- TOP3A | c.2472C>T p.V824= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs551660741, COSV58176491; called by muse, mutect2, varscan2
- TRIM41 | c.1884C>G p.L628= | Silent (SNP) | VAF 9/158 reads (6%) | catalogued as COSV59318410; called by muse, mutect2
- TSPAN3 | c.252C>T p.A84= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as COSV51214773; called by muse, mutect2, varscan2
- ZC3H4 | c.2325G>A p.Q775= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as COSV53411782; called by muse, mutect2, varscan2
- AC024940.1 | n.4781C>T | RNA (SNP) | VAF 10/65 reads (15%) | catalogued as rs889863405; called by muse, mutect2, varscan2
- ASIC2 | c.556-179682G>C | Intron (SNP) | VAF 15/33 reads (45%) | catalogued as COSV56759018; called by muse, mutect2, varscan2
- CAMTA1 | c.*2G>A | 3'UTR (SNP) | VAF 10/55 reads (18%) | catalogued as COSV50012453; called by muse, mutect2
- FSIP1 | c.*2C>G | 3'UTR (SNP) | VAF 17/60 reads (28%) | catalogued as COSV52954005, COSV99527657; called by muse, mutect2, varscan2
- MAGI1 | c.3635-1989G>C | Intron (SNP) | VAF 27/172 reads (16%) | catalogued as COSV58321253; called by muse, mutect2, varscan2
- RNF216 | c.202-63G>C | Intron (SNP) | VAF 47/198 reads (24%) | catalogued as COSV66290014; called by muse, mutect2, varscan2
- WT1 | chr11:32439065 G>C | 5'Flank (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2
